Gene-level copy-number profile of tumor specimen TCGA-OR-A5JZ-01A from TCGA case TCGA-OR-A5JZ, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 60.8 years (22,218 days).
Specimen TCGA-OR-A5JZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.321dab35-c61e-45b9-8af4-17ab9275da5b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5JZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3773b4c3-8c20-474e-bf5a-111e9b4f222b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 19; copy number 2: 47,984; copy number 3: 181; copy number 4: 11,126; copy number 6: 508.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5JZ-01A-11D-A29H-01): tumor purity 0.95, ploidy 1.21, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 508 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–20,575,873, 357 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr5:26,711,551–35,429,277, 118 genes, copy number 6 (broad region; genes not listed).
- chr5:35,632,963–35,633,024, 1 gene, copy number 6: RNU7-130P.
- chr5:37,246,173–37,753,435, 10 genes, copy number 6 (within-gene range 4–6): RN7SL37P, AC025449.2, AC025449.1, NUP155, RNU7-75P, AC117532.1, WDR70, KCTD9P5, RNU6-1190P, RNU6-484P.
- chr5:38,258,409–38,465,480, 1 gene, copy number 6 (within-gene range 4–6): EGFLAM.
- chr5:38,345,347–39,524,726, 21 genes, copy number 6: EGFLAM-AS3, EGFLAM-AS2, EGFLAM-AS1, AC091839.1, AC010457.1, LIFR, LIFR-AS1, MIR3650, AC010425.1, OSMR-AS1, AC091435.1, AC091435.2, OSMR, RICTOR, AIG1P1, AC008964.1, FYB1, GOLGA5P1, C9, DAB2, LINC02104.

Autosomal genes at a single copy (total copy number 1): 19. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
